Gene-level copy-number profile of tumor specimen HCM-SANG-1313-C18-06A-01D-A80T-32 from HCMI case HCM-SANG-1313-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1313-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5872baa-5dcd-4c48-9131-d3affefe81ce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1313-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/4af0dbef-a139-4b3e-a809-2ff177d70b45

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 26; copy number 2: 6,028; copy number 3: 10,044; copy number 4: 30,360; copy number 5: 7,528; copy number 6: 2,632; copy number 7: 1,558; copy number 8: 43; copy number 9: 34; copy number 10: 26; copy number 12: 1; copy number 15: 31; copy number 17: 45; copy number 27: 8; copy number 31: 1; copy number 35: 3.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr5:79,284,132–79,284,918, 1 gene (within-gene range 0–3): RPS3AP20.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr17:18,450,244–18,506,313, 6 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–2): AL138808.1.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–3): TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 149 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:65,309,855–65,310,953, 1 gene, copy number 9: STARP1.
- chr13:70,459,464–71,168,417, 4 genes, copy number 9: RNU6-54P, AL445264.1, MTCL1P1, LINC00348.
- chr13:71,437,966–71,914,178, 5 genes, copy number 10: DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21.
- chr13:72,703,693–74,259,976, 21 genes, copy number 9: RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402.
- chr13:74,289,100–74,289,214, 1 gene, copy number 9: RNY1P5.
- chr13:74,434,538–74,565,445, 2 genes, copy number 9 (within-gene range 5–9): AL355390.2, LINC00347.
- chr17:22,090,743–22,288,301, 5 genes, copy number 9: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2.
- chr17:39,401,793–39,451,272, 2 genes, copy number 35 (within-gene range 5–35): AC005288.1, MED1.
- chr17:39,687,914–39,864,312, 7 genes, copy number 27 (within-gene range 5–27): ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:43,360,041–43,361,361, 1 gene, copy number 35: AC109326.1.
- chr17:58,353,676–58,417,595, 1 gene, copy number 27 (within-gene range 5–27): RNF43.
- chr17:59,619,689–60,666,280, 45 genes, copy number 17 (within-gene range 5–17): CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,810,165–60,811,462, 1 gene, copy number 31 (within-gene range 5–31): KRT18P61.
- chr20:31,257,664–32,335,011, 53 genes, copy number 10–15: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
